Surgical pathology report (de-identified scan), TCGA case TCGA-BR-4257, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-4257-01A (Primary Tumor).

STOMACH TISSUE CHECKLIST. Specimen type: Gastrectomy. Tumor Site: Antrum. Tumor configuration: Ulcerating. Tumor size: 8 x 6 x 1.5 cm. Histologic type: Adenocarcinoma. Histologic grade: Moderately differentiated. Extent of invasion: Not specified. Lymph nodes: Not specified. Margins — Proximal margin: Not specified. Distal margin: Not specified. Omental (radial) margin: Not specified. Lymphatic invasion: Not specified. Venous invasion: Not specified. Perineural invasion: Not specified. Additional pathologic findings: Not specified. Comments: None.

Source: NCI Genomic Data Commons file fd5db2e7-24ed-4037-b60c-9aa6385168e9 (TCGA-BR-4257.83E189DF-3E69-41E9-886E-E22BB6BD6E50.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).